Surgical pathology report (de-identified scan), TCGA case TCGA-B2-5641, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-B2-5641-01A (Primary Tumor).

SPECIMEN

Left kidney

CLINICAL NOTES

PRE-OP DIAGNOSIS: Left renal tumor.

GROSS DESCRIPTION

The specimen is received unfixed labeled "left kidney" and consists of a kidney and surrounding adipose tissue. The entire specimen measures 21 x 14 x 7 cm. The kidney measures 11.7 x 7 x approximately 5 cm. At one pole of the kidney there is a red, seemingly well-circumscribed, tumor measuring 3 x 2 cm. On additional sectioning, the tumor is up to 4 cm in diameter and a portion of the tumor is taken for research purposes. Sections after fixation

Block summary: 1,2 margins of resection; 3-7 tumor; 8,9 normal kidney..

MICROSCOPIC DESCRIPTION

Tumor type: Clear cell type renal cell carcinoma
grade: 3 (out of 4; Fuhrman et al. AJSP 6:655,
size: 4 cm
Renal capsule: Negative for malignancy
Renal sinus: Negative for malignancy
Vascular invasion: Absent
Hilar margins: Negative for malignancy
Kidney away from tumor: Normal
pTNM Stage: T1a

DIAGNOSIS

Kidney, left, resection:
Clear cell type renal cell carcinoma, Fuhrman grade 3.

Source: NCI Genomic Data Commons file 5ec3e01b-e600-4296-a7d9-29bab8d12865 (TCGA-B2-5641.4BE0A476-EA29-414C-808F-3C7B07C3FECD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).